TCGA case TCGA-GN-A9SD — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: Roswell. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec4c4296-6ab4-420c-80a4-e7a34b9bf4a2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Dead; Days to death: 1,807 days (4.9 years).

Diagnoses (9)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.4; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: Progression; Age at diagnosis: 63.6 years (23,217 days); Days to diagnosis: 1,366 days (3.7 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 59.8 years (21,851 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dactinomycin + Melphalan; Days to treatment start: 1,268 days (3.5 years); Days to treatment end: 1,268 days (3.5 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Melphalan; Days to treatment start: 1,366 days (3.7 years); Days to treatment end: 1,366 days (3.7 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vemurafenib; Days to treatment start: 1,519 days (4.2 years); Days to treatment end: 1,687 days (4.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,738 days (4.8 years); Days to treatment end: 1,744 days (4.8 years); Treatment dose: 20 Gy; Treatment outcome: Partial Response; Number of fractions: 5; Treatment anatomic sites: Distant Site.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Extremities; Ulceration indicator: No.
   Pathology details: Breslow thickness category: <=1 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 62.9 years (22,988 days); Days to diagnosis: 1,137 days (3.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,184 days (3.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
5. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 63.3 years (23,118 days); Days to diagnosis: 1,267 days (3.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
6. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 63.7 years (23,275 days); Days to diagnosis: 1,424 days (3.9 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
7. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 63.9 years (23,357 days); Days to diagnosis: 1,506 days (4.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
8. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 64.4 years (23,510 days); Days to diagnosis: 1,659 days (4.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,679 days (4.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
9. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Vertebral column. Age at diagnosis: 64.4 years (23,538 days); Days to diagnosis: 1,687 days (4.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (7 entries)
- Day 1,137 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,137 days (3.1 years).
- Day 1,267 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,267 days (3.5 years).
- Day 1,424 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,424 days (3.9 years).
- Day 1,506 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,506 days (4.1 years).
- Day 1,659 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,659 days (4.5 years).
- Day 1,687 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Vertebral column; Days to progression: 1,687 days (4.6 years).
- Days to follow up: 1,807 days (4.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 1.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 97 kg; Height: 158 cm; BMI: 38.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GN-A9SD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 170 mg.
  Slide TCGA-GN-A9SD-06A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-GN-A9SD-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GN-A9SD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: Yes; Tumor status: With tumor; Breslow thickness at diagnosis: 0.5; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 1; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Drug treatment 1: Pharmaceutical therapy drug name: actinomycin d; Treatment best response: Clinical Progressive Disease.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Patient had isolated limb profusion for the malignancy submitted to TCGA prior to tumor resection, treated with Actinomycin D and Melphalan.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,807 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,807 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,137 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GN-A9SD-06A-11D-A400-01): tumor purity 0.4, ploidy 1.81, whole-genome doublings 0.
